Surgical pathology report (de-identified scan), TCGA case TCGA-12-1097, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1097-01B (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

[REDACTED] presented the weekend of [REDACTED] with severe headache. He went to the urgent care on [REDACTED] and followed up with his primary care physician on [REDACTED]. He was treated conservatively. On the morning on [REDACTED] while at work he had difficulty reading what was on a piece of paper. Over the next two to three days he experienced worsening confusion and went back to his primary care physician on [REDACTED], who ordered a CT scan for [REDACTED] revealing evidence of a large right occipital abnormality. He had a follow-up MRI with contrast revealing an enhancing lesion consistent with high-grade primary glioma. He was taken to the operating room on [REDACTED] with [REDACTED] for a biopsy confirming the diagnosis.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received for frozen section is a 72.1 gram roughly 6 x 6 x 5 cm piece of brain. Sectioning reveals a focal 2 x 1 x 1 cm subcortical hemorrhage. There is also a diffuse area of necrosis approximately 3 x 2 x 3 cm. Representative sections are submitted, including the aforementioned area of hemorrhage and necrosis, in blocks A1-5.

B. "Brain tissue (BF1)", received for frozen section is a less than 1 mm fragment of brain tissue which is completely submitted in block B1.

C. "Brain tissue (CF1)", received for frozen section is a less than 0.1 mm fragment of brain tissue. The frozen section remnant is submitted in block C1.

D. "Brain tissue", received fresh and placed in formalin is a 3.5 x 3 x 1 cm aggregate of brain tissue. Representative sections are submitted in D1-2.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue":AF1-high grade glioma. Glioblastoma [REDACTED].

B. "Brain tissue":BF1-high grade glioma [REDACTED].

C. "Brain tissue":CF1-high grade glioma [REDACTED].

MICROSCOPIC EXAMINATION:

The tissue is brain that is infiltrated by neoplastic proliferation of malignant astrocytes characterized by intermediate fibrillar astrocytes. The tumor exhibits vascular proliferation and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

B. "BRAIN TISSUE" (CRANIOTOMY):

HIGH GRADE ASTROCYTOMA.

C. "BRAIN TISSUE" (CRANIOTOMY):

HIGH GRADE ASTROCYTOMA.

[page 2 of 3]
D. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (44% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (90% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (65% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (72% OF TUMOR CELLS EXHIBIT LOSS)

9p21 - LOSS (68% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (44% OF TUMOR CELLS EXHIBIT LOSS)

4 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

FISH DATA INDICATE THAT PTEN GENE IS LOST WHILE IMMUNOHISTOCHEMISTRY INDICATES THAT PTEN PROTEIN EXPRESSION IS INTACT. THE SIGNIFICANCE OF THIS DISCREPANCY IS UNKNOWN, BUT IT MAY REPRESENT A FALSE POSITIVE BY IMMUNOHISTOCHEMISTRY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED], BLOCK A3).

PROLIFERATION INDEX INTERPRETATION: MODERATE PROLIFERATION INDEX (5% OF TUMOR CELLS EXHIBIT STAINING)

MGMT - NEGATIVE (20% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 90% OF TUMOR CELLS)

EGFR vIII - POSITIVE (2+ IN 30% OF TUMOR CELLS)

PTEN - INTACT (3+ IN 90% OF TUMOR CELLS)

[page 3 of 3]
pS6 - POSITIVE (2+ IN 40% OF TUMOR CELLS)

pAKT - POSITIVE (2+ IN 80% OF TUMOR CELLS)

pMAPK - POSITIVE (3+ IN 30% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file 70d1c89f-3038-4716-a6f1-1a30d81b0173 (TCGA-12-1097.6B38CC54-221E-45C5-B287-F4C7B2F8755D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).